Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A52B, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A52B-01A (Primary Tumor).

[page 1 of 2]
HISTOPATHOLOGY REPORT

CLINICAL NOTES :

Robotic prostatectomy, clinically T3, R) side, Gleason 5+5 all cores PSA 7.

MACROSCOPIC :

Specimen 1. Labelled with patient details. A radical prostatectomy specimen 50 x 55 x 49 mm weighing 77 gm.

Block designation:

Blocks A, B Right apex Blocks C, D Left apex
Blocks E to G Right base Blocks H to J Left base
Blocks K to R Apex to base right lobe Blocks S to Z Apex to base left lobe
Block E to G Right seminal vesicle Block H to J Left seminal vesicle
Anterior black, remainder blue. Fresh tissue reserved for tissue banking. P26

Specimen 2. Labelled bladder neck biopsy. Tan tissue 3 mm. A1

Specimen 3. Labelled right pelvic lymph node. Fatty tissue up to 125mm with nodes up to 20 mm. A to C - 1 node each bisected, D - 3 nodes. P4

Specimen 4. Labelled L) pelvic lymph node. Fatty tissue up to 40 mm with a node up to 10 mm. P1

MICROSCOPIC :

Specimen 1: Sections from the prostate confirm a large volume peripheral zone prostatic adenocarcinoma extending from the apex to base and involving both right and left lobes. It is Gleason grade 5+4=9. There is multifocal lymphovascular and perineural invasion. There is extensive extraprostatic extension posterolaterally in the right and left lobes as well as in the step sections through the right and left base up to 17 x 4 mm. There is extension the both right and left bladder neck margins up to 15 mm. Direct invasion of both right and left seminal vesicles is present.

Specimen 2: Sections confirm bladder neck tissue showing a focus of carcinoma with similar features to that seen in specimen (1).

Specimens 3 & 4: Sections confirm 7 lymph nodes (6 right and 1 left) showing no evidence of malignancy.

CONCLUSION:

Specimen 1: Radical prostatectomy -- Bilateral peripheral zone prostatic adenocarcinoma; Gleason score 5+4=9 with lymphovascular invasion, extensive extraprostatic extension, positive pathologic margin and seminal vesicle invasion. Lymph nodes are clear. Pathologic stage T3bN0

Specimen 2: Bladder neck biopsy -- Prostatic adenocarcinoma.

Specimens 3 & 4: Right and left pelvic lymph node -- No evidence of malignancy in 7 lymph nodes.

SYNOPTIC REPORT: CARCINOMA OF PROSTATE

Specimen type : Radical prostatectomy

Tumour type: Peripheral zone carcinoma (acinar type)

Gleason score: 5+4=9

Site: See volumetric analysis.

Unifocal/Multifocal : Multifocal

Perineural invasion : Multifocal

Lymphovascular invasion : Multifocal

ICB-0-3

adenocarcinoma, acinar 8-50/3
Site: prostate, NOS c61.9

hw
11/12/12

Unilateral/Synchronous Primary Noted		☒

[page 2 of 2]
Extraprostatic extension : There is extensive extraprostatic extension posterolaterally in the right and left lobes as well as in the step sections through the right and left base up to 17 x 4 mm

Seminal vesicle involvement : Direct invasion of both right and left seminal vesicles is present

Pathological resection margin status : There is extension the both right and left bladder neck margins up to 15 mm

Presence of PIN : Multifocal

Lymph nodes: Site: Right and left pelvic
Number of nodes present: 7 (6 right and 1 left)
Number of nodes positive: 0

Tumour Volume: Peripheral Zone (black): 42.4cc

Pathologic stage: T3bN0

Reported by: .

Source: NCI Genomic Data Commons file a1ff226a-7854-46c3-91eb-0b6f36ee457d (TCGA-J9-A52B.68F82D7A-CF0F-404F-8B39-7B2EB3DE9418.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).